Somatic mutation profile of tumor specimen 0DI5FO from CCDI case PBBVJR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.6 years (6,048 days).
Specimen 0DI5FO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c82af62-1313-4211-8824-4b345112954b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5EI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b497b2-59c1-4b70-a565-9834f21954db

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 241/435 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC011462.1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 113/311 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778046117; called by muse, mutect2, varscan2
- PSMD6 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 46/996 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs757884032, COSV55759181; called by muse, mutect2
- STAG1 | c.3305C>G p.T1102S | Missense Mutation (SNP) | VAF 42/1345 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV52605889; called by muse, mutect2
- TRAF7 | c.1193C>G p.P398R | Missense Mutation (SNP) | VAF 207/590 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58218265, COSV58219586; called by muse, mutect2, varscan2
- UBTF | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 395/1087 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100255838; called by muse, mutect2, varscan2
- CCDC88C | c.3364A>T p.N1122Y | Missense Mutation (SNP) | VAF 26/674 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KAT2A | c.2084G>A p.C695Y | Missense Mutation (SNP) | VAF 86/1749 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- LRRIQ3 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 617/1586 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC5A7 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 576/1556 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TMPRSS5 | c.573G>A p.Q191= | Silent (SNP) | VAF 369/1008 reads (37%) | called by muse, mutect2, varscan2
- CUL3 | c.2030-32A>G | Intron (SNP) | VAF 24/766 reads (3%) | catalogued as rs1378467824; called by muse, mutect2
- CUL3 | c.2030-34A>T | Intron (SNP) | VAF 20/726 reads (3%) | called by muse, mutect2
- IPO8 | c.639+75T>A | Intron (SNP) | VAF 9/122 reads (7%) | called by mutect2, varscan2
- OSR1 | c.-32-17T>C | Intron (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
